Gene-level copy-number profile of tumor specimen BLGSP-71-19-00113-01A from CGCI case BLGSP-71-19-00113, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 3.3 years (1,198 days).
Specimen BLGSP-71-19-00113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Cervical; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 553636fc-fc5b-4858-9aa4-83aeb1d5b67e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-19-00113-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/77332010-f23b-430d-bfd1-8605a5877e18

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 3,019; copy number 2: 55,356; copy number 3: 224; copy number 4: 238; copy number 5: 8; copy number 6: 26.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 33 genes (within-gene range 0–3): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-29, IGKV2-30.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 34 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,269,491–38,318,861, 8 genes, copy number 5 (within-gene range 3–5): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr14:22,197,446–22,482,959, 1 gene, copy number 6 (within-gene range 4–6): AC244502.1.
- chr14:22,304,054–22,483,069, 24 genes, copy number 6: TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53.
- chr14:22,547,506–22,552,156, 1 gene, copy number 6: TRAC.

Autosomal genes at a single copy (total copy number 1): 163. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
